Gene-level copy-number profile of tumor specimen HCM-SANG-0275-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0275-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0275-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c7bc528-998c-466e-a0d9-cb4a75103e37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0275-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/542dd6e7-fdca-4a48-88b5-e728a45e85f7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 122; copy number 2: 5,745; copy number 3: 18,747; copy number 4: 20,972; copy number 5: 5,467; copy number 6: 3,522; copy number 7: 3,098; copy number 8: 805; copy number 9: 346; copy number 11: 1; copy number 13: 2; copy number 21: 32.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–2): KRT8P44.
- chr15:21,298,233–21,951,323, 38 genes: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr16:7,004,007–7,126,639, 2 genes (within-gene range 0–1): RNU6-328P, AC022206.1.
- chr17:19,600,860–19,633,825, 7 genes: AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–7): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 381 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:26,965,967–27,989,584, 32 genes, copy number 21: AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P.
- chr20:11,345,383–11,345,855, 1 gene, copy number 11: RPS11P1.
- chr20:16,177,933–22,966,063, 134 genes, copy number 9 (broad region; genes not listed).
- chr20:24,931,840–33,731,828, 160 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr20:51,596,514–55,684,915, 45 genes, copy number 9: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr22:18,361,820–18,530,573, 9 genes, copy number 9–13: FAM230J, AC011718.1, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Autosomal genes at a single copy (total copy number 1): 122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
